Somatic mutation profile of tumor specimen C3N-01405-01 (aliquot CPT0105330009) from CPTAC case C3N-01405, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 59.2 years (21,609 days).
Specimen C3N-01405-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1376dd26-b9e3-48f3-8b0e-f850499aa6a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01405-31 (Blood Derived Normal), aliquot CPT0107800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18b06138-db55-4623-9acf-ee2655c94e9f

The open-access MAF lists 543 somatic variants for this specimen: 377 protein-altering or splice-affecting, 101 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 325, Silent 101, Intron 29, Nonsense Mutation 24, Frame Shift Del 11, 3'UTR 10, RNA 9, Splice Region 8, 3'Flank 7, Splice Site 7, 5'Flank 5, 5'UTR 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs137854557, CM1111787, CS992455, COSV62194445; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 42/165 reads (25%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ACADS | c.796-1G>T p.X266_splice | Splice Site (SNP) | VAF 105/358 reads (29%) | catalogued as COSV54369532; called by muse, mutect2, varscan2
- ACBD5 | c.1171C>T p.P391S (on ENST00000375888 / NM_001352568.1; = p.P382S on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs763905714; called by muse, mutect2
- ACTN2 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.357); catalogued as rs200854335, COSV100857079, COSV63975491, COSV63975814; ClinVar: uncertain significance; called by muse, mutect2
- ADAM19 | c.2480G>C p.R827T | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV57433346; called by muse, mutect2, varscan2
- ADAMTS16 | c.2419G>T p.G807C | Missense Mutation (SNP) | VAF 85/670 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777426296; called by muse, mutect2, varscan2
- ADGRB2 | c.1499G>T p.R500L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99925865; called by muse, mutect2, varscan2
- ADGRE1 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.622); catalogued as COSV51677645; called by muse, mutect2, varscan2
- ARSF | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.95); catalogued as COSV63840174; called by muse, mutect2, varscan2
- ATG9B | c.2209C>A p.Q737K | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.082); catalogued as rs534489154; called by muse, mutect2
- ATP13A5 | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.216); catalogued as rs1388586967, COSV100664652; called by muse, mutect2, varscan2
- ATP7B | c.3886G>T p.D1296Y | Missense Mutation (SNP) | VAF 120/478 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM023025; called by muse, mutect2, varscan2
- BRINP3 | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs539178233, COSV66544173; called by muse, mutect2
- CEP290 | c.3181A>G p.M1061V | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1201486566; called by muse, mutect2, varscan2
- CHST2 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV58887100; called by muse, mutect2, varscan2
- COL2A1 | c.3317G>A p.R1106Q | Missense Mutation (SNP) | VAF 151/474 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1453392906; called by muse, mutect2, varscan2
- COL4A2 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV64636518; called by muse, mutect2, varscan2
- COPG2 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs782715453, COSV58406911; called by muse, mutect2, varscan2
- CPZ | c.907-1G>T p.X303_splice (on ENST00000360986 / NM_001014447.3; = p.X292_splice on NM_003652.3) | Splice Site (SNP) | VAF 39/144 reads (27%) | catalogued as COSV59921706; called by muse, mutect2, varscan2
- CREBBP | c.4915G>T p.A1639S | Missense Mutation (SNP) | VAF 83/357 reads (23%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.959); catalogued as rs770154926; called by muse, mutect2, varscan2
- CSMD3 | c.2366G>T p.G789V (on ENST00000297405 / NM_001363185.1; = p.G685V on NM_052900.3) | Missense Mutation (SNP) | VAF 39/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52096969; called by muse, mutect2, varscan2
- CTNNA2 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58151023; called by muse, mutect2
- CTNND2 | c.1624C>A p.P542T | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV58878015, COSV58912875; called by muse, varscan2
- CYP2W1 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58271856; called by muse, mutect2, varscan2
- DAZAP1 | c.1049-7C>T | Splice Region (SNP) | VAF 64/199 reads (32%) | catalogued as rs750975077; called by muse, mutect2, varscan2
- DBX2 | c.922G>T p.G308W | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.628); catalogued as rs1325875839; called by muse, mutect2, varscan2
- DNAH1 | c.10048C>T p.P3350S | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.729); catalogued as rs1290501284; called by muse, mutect2, varscan2
- ECT2L | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756100667; called by muse, mutect2, varscan2
- EPHA5 | c.1243C>A p.L415I | Missense Mutation (SNP) | VAF 153/468 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV99900386, COSV99902470; called by muse, mutect2, varscan2
- ESCO1 | c.2255G>A p.R752K | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as rs78344029; called by muse, mutect2, varscan2
- EVC2 | c.3463C>T p.P1155S | Missense Mutation (SNP) | VAF 67/206 reads (33%) | catalogued as rs1560115246; called by muse, mutect2, varscan2
- F13B | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.209); catalogued as COSV100803352; called by muse, mutect2, varscan2
- FCRL3 | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63841810; called by muse, mutect2
- FYB1 | c.1868A>T p.D623V | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs746020807; called by muse, mutect2, varscan2
- GAK | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 35/328 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs141655027; called by muse, mutect2, varscan2
- GPR158 | c.2586del p.E863Kfs*44 | Frame Shift Del (DEL) | VAF 90/363 reads (25%) | catalogued as COSV66271697; called by mutect2, pindel, varscan2
- GPR174 | c.902G>T p.R301I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV52132025; called by muse, mutect2, varscan2
- HAPLN2 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 122/246 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as rs1188183402; called by muse, mutect2, varscan2
- HIBADH | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 82/233 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1337733794, COSV55313578; called by muse, mutect2, varscan2
- HNRNPR | c.1357G>C p.G453R | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.543); catalogued as rs748400587, COSV56421271; called by muse, mutect2
- IGSF9B | c.65-6C>T | Splice Region (SNP) | VAF 26/153 reads (17%) | catalogued as rs575396187; called by muse, mutect2, varscan2
- IRAK1 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs782095517; called by muse, mutect2, varscan2
- ITIH1 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.109); catalogued as rs1008720303; called by muse, mutect2, varscan2
- KCNA10 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs771463924; called by muse, mutect2, varscan2
- KCNB2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.74); catalogued as COSV73052836; called by muse, mutect2
- KCNMB1 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 80/384 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV51131872; called by muse, mutect2, varscan2
- KLHL3 | c.1450+1G>T p.X484_splice | Splice Site (SNP) | VAF 62/237 reads (26%) | catalogued as COSV59055110; called by muse, mutect2, varscan2
- LINC02843 | n.219G>T | Splice Region (SNP) | VAF 57/259 reads (22%) | catalogued as rs919133127; called by muse, mutect2, varscan2
- LRRC14 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.689); catalogued as rs1328962715; called by muse, mutect2
- LYNX1-SLURP2 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 120/351 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as rs1225345106; called by muse, mutect2, varscan2
- MSR1 | c.12G>T p.W4C | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV100027280; called by muse, mutect2, varscan2
- MYOT | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 86/314 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.197); catalogued as rs749292789; called by mutect2, varscan2
- NAV2 | c.4562C>T p.T1521I (on ENST00000396087 / NM_001244963.2; = p.T1498I on NM_145117.5) | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV60665302; called by muse, mutect2, varscan2
- NF1 | c.7405G>A p.E2469K (on ENST00000358273 / NM_001042492.3; = p.E2448K on NM_000267.3) | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV100647981; called by muse, mutect2
- NTF3 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs777521890, COSV58417756; called by muse, mutect2, varscan2
- OR14I1 | c.722C>A p.P241H | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61201233; called by muse, mutect2, varscan2
- OR4C15 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV58951359; called by muse, mutect2, varscan2
- OR5D14 | c.141G>T p.M47I | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV59456845; called by muse, mutect2, varscan2
- PCARE | c.3608C>A p.P1203Q | Missense Mutation (SNP) | VAF 110/442 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.491); catalogued as COSV59053032; called by muse, mutect2, varscan2
- PCDHGB4 | c.1549G>T p.A517S | Missense Mutation (SNP) | VAF 46/414 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.147); catalogued as COSV53946726; called by muse, mutect2, varscan2
- PPP2R1B | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs1329566207; called by muse, mutect2, varscan2
- PPP6R1 | c.2509C>G p.P837A | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV58984744; called by muse, mutect2, varscan2
- PRPH | c.543G>C p.Q181H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as rs758122139; called by mutect2, varscan2
- RALGAPA1 | c.2426G>A p.R809Q | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.645); catalogued as rs1265297148; called by muse, mutect2
- RCOR1 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 23/97 reads (24%) | catalogued as rs1445861824; called by muse, mutect2, varscan2
- REG1A | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52068316; called by muse, mutect2, varscan2
- RGS22 | c.3740G>A p.S1247N | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1167874709; called by muse, mutect2, varscan2
- RIMS2 | c.1297C>T p.P433S (on ENST00000666250 / NM_001348490.2; = p.P241S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1020266564, COSV51686134, COSV51717691; called by muse, mutect2
- RNF149 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV54865204; called by muse, mutect2, varscan2
- SACS | c.10279G>C p.G3427R | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.843); catalogued as COSV66537167; called by muse, mutect2, varscan2
- SCN7A | c.2623A>T p.S875C | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV69271123; called by muse, varscan2
- SEC16B | c.2860C>A p.L954M | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV57630891; called by muse, mutect2, varscan2
- SIDT1 | c.1985G>T p.R662L | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs376051655; called by muse, mutect2, varscan2
- SIRPD | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs551329622; called by muse, mutect2, varscan2
- SLC9A1 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1189050207, COSV56053171; called by muse, mutect2, varscan2
- SLCO5A1 | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV52657021; called by muse, mutect2, varscan2
- SOCS2 | c.304G>T p.G102* | Nonsense Mutation (SNP) | VAF 97/303 reads (32%) | catalogued as COSV61392330; called by muse, mutect2, varscan2
- SPATA17 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99055525; called by muse, mutect2, varscan2
- SPATA31A3 | c.3025G>A p.V1009I | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.854); catalogued as rs1001391971; called by mutect2, varscan2
- SPOP | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 79/265 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV61652768; called by muse, mutect2, varscan2
- SPRR3 | c.469G>C p.V157L | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV99768666; called by muse, mutect2
- SPTA1 | c.2820G>T p.K940N | Missense Mutation (SNP) | VAF 211/472 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759064678, COSV63756277, COSV63759629; called by muse, mutect2, varscan2
- SPTA1 | c.2374C>A p.L792I | Missense Mutation (SNP) | VAF 257/559 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV63752319; called by muse, mutect2, varscan2
- SRSF6 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 56/263 reads (21%) | catalogued as COSV54828744; called by muse, mutect2, varscan2
- ST18 | c.1711C>A p.H571N | Missense Mutation (SNP) | VAF 90/356 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as rs1221624065; called by muse, mutect2, varscan2
- ST6GAL2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 17/98 reads (17%) | PolyPhen benign (0.2); catalogued as rs751305558, COSV64528573; called by muse, mutect2, varscan2
- STAM | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs551633032; called by muse, mutect2, varscan2
- TAS1R1 | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.113); catalogued as rs926332577; called by muse, mutect2, varscan2
- TAS2R9 | c.453T>A p.D151E | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.083); catalogued as COSV99553728; called by muse, mutect2
- TDRD5 | c.2161G>C p.D721H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV99675686; called by muse, mutect2, varscan2
- TDRD9 | c.1432C>A p.Q478K | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV59154024; called by muse, mutect2, varscan2
- TENM4 | c.4744A>G p.I1582V | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs758518569; called by muse, mutect2, varscan2
- TMEM200C | c.79C>G p.R27G | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104431311; called by muse, mutect2, varscan2
- TMEM209 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs982542495; called by muse, mutect2, varscan2
- TNR | c.3937G>T p.G1313W | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99686773; called by mutect2, varscan2
- TPO | c.711C>G p.I237M | Missense Mutation (SNP) | VAF 103/531 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs756113203, COSV61101342; called by muse, mutect2, varscan2
- TPO | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 89/479 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs761068957, COSV61095680; called by muse, mutect2, varscan2
- TROAP | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV57745473; called by muse, mutect2, varscan2
- TTN | c.698C>G p.S233* | Nonsense Mutation (SNP) | VAF 22/338 reads (7%) | catalogued as rs868264146; called by muse, mutect2
- TVP23B | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.19); catalogued as rs1360595487; called by muse, mutect2, varscan2
- UBR4 | c.13348G>A p.D4450N | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868556077; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2301G>T p.K767N | Missense Mutation (SNP) | VAF 90/344 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99691940; called by muse, mutect2, varscan2
- UNC80 | c.8099C>T p.P2700L | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as rs1403011787, COSV55892331; called by muse, mutect2, varscan2
- VARS2 | c.1883G>T p.R628L | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58911399; called by muse, mutect2, varscan2
- VEGFB | c.375-7T>G | Splice Region (SNP) | VAF 12/68 reads (18%) | catalogued as COSV58536661, COSV58537558; called by muse, varscan2
- VEPH1 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 37/318 reads (12%) | catalogued as rs970724041, COSV100747374; called by muse, mutect2, varscan2
- WDR59 | c.484A>G p.N162D | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1170442540, COSV50937274; called by muse, mutect2, varscan2
- XYLT2 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 45/364 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs142963935; called by muse, mutect2, varscan2
- ZFYVE26 | c.6331G>C p.E2111Q | Missense Mutation (SNP) | VAF 53/396 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV61331939; called by muse, mutect2, varscan2
- ZNF329 | c.403G>C p.V135L | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753785907; called by muse, mutect2, varscan2
- ZNF423 | c.1043G>C p.C348S (on ENST00000563137 / NM_001379286.1; = p.C340S on NM_015069.4) | Missense Mutation (SNP) | VAF 109/432 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV52204519; called by muse, mutect2, varscan2
- ZNF462 | c.1333C>G p.P445A | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.062); catalogued as COSV99472702; called by muse, mutect2, varscan2
- ZNF492 | c.1064A>G p.H355R | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs755026518; called by mutect2, varscan2
- AC006059.2 | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ADAMTS20 | c.1220A>T p.H407L | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL3 | c.572T>A p.L191* | Nonsense Mutation (SNP) | VAF 45/195 reads (23%) | called by muse, mutect2, varscan2
- ADCY3 | c.1749G>T p.E583D | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AFTPH | c.910A>T p.I304L | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGRN | c.3335G>T p.C1112F | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALK | c.4345T>A p.S1449T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- AMY2B | c.1489T>G p.S497A | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANGPTL6 | c.479T>A p.L160Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- APOB | c.9197G>T p.G3066V | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ARFGEF1 | c.4626G>T p.W1542C | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ARL14EP | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2
- ARSA | c.671A>T p.Y224F | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASXL3 | c.1286C>A p.P429Q | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ATP2B4 | c.2902G>T p.V968L | Missense Mutation (SNP) | VAF 58/443 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- BAIAP3 | c.2733G>T p.K911N | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- BCL11B | c.1270G>A p.A424T (on ENST00000357195 / NM_001282237.2; = p.A353T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- BCL11B | c.796C>A p.P266T (on ENST00000357195 / NM_001282237.2; = p.P195T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- BCOR | c.4197G>T p.K1399N (on ENST00000378444 / NM_001123385.2; = p.K1365N on NM_017745.6) | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- BFSP2 | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 92/461 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BICRAL | c.2807G>T p.G936V | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- BNC2 | c.1483C>A p.P495T | Missense Mutation (SNP) | VAF 104/440 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRCA2 | c.3270G>T p.M1090I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRSK2 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- BSX | c.95C>A p.P32Q | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTNL2 | c.963G>C p.E321D | Missense Mutation (SNP) | VAF 89/321 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- C5 | c.1267A>G p.N423D | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C6 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 230/528 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CACNA1A | c.4680C>A p.Y1560* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- CACNA1G | c.1287del p.G430Afs*134 | Frame Shift Del (DEL) | VAF 116/557 reads (21%) | called by mutect2, pindel, varscan2
- CACNA1G | c.6790G>T p.E2264* | Nonsense Mutation (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- CAPN3 | c.1038C>G p.F346L | Missense Mutation (SNP) | VAF 54/341 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPZA3 | c.141A>T p.Q47H | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCDC148 | c.1348C>A p.Q450K | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CCDC168 | c.17457G>T p.W5819C | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.041); called by muse, varscan2
- CCDC168 | c.9062T>G p.L3021W | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CCDC73 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH18 | c.1700C>G p.P567R | Missense Mutation (SNP) | VAF 128/259 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH23 | c.6412G>C p.E2138Q | Missense Mutation (SNP) | VAF 165/517 reads (32%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CEP78 | c.941G>T p.R314M | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- CHL1 | c.1585T>A p.L529M (on ENST00000397491 / NM_001253387.1; = p.L545M on NM_006614.4) | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- CLPSL2 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- CMYA5 | c.11747G>T p.S3916I | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2
- CNTN5 | c.1869T>A p.F623L | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL11A1 | c.1889A>T p.D630V | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A5 | c.5074G>T p.G1692* | Nonsense Mutation (SNP) | VAF 28/160 reads (18%) | called by muse, varscan2
- CPED1 | c.1901C>A p.P634H | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CSMD3 | c.1816G>A p.G606S (on ENST00000297405 / NM_001363185.1; = p.G502S on NM_052900.3) | Missense Mutation (SNP) | VAF 102/572 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNND2 | c.2909T>A p.V970E | Missense Mutation (SNP) | VAF 46/659 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CXorf66 | c.89-1G>T p.X30_splice | Splice Site (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- DGKG | c.296A>C p.E99A | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DISC1 | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 74/552 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.083); called by muse, varscan2
- DNAH7 | c.4568A>T p.N1523I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- DNAJC10 | c.1271A>T p.K424I | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DYNC2LI1 | c.664A>G p.K222E | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- EBF1 | c.45G>T p.M15I | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EED | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- EGFLAM | c.1313T>A p.M438K | Missense Mutation (SNP) | VAF 105/241 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- EHD3 | c.656A>T p.N219I | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EI24 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 53/205 reads (26%) | called by muse, mutect2, varscan2
- ELP2 | c.2227_2240del p.G743Kfs*11 | Frame Shift Del (DEL) | VAF 50/406 reads (12%) | called by mutect2, pindel
- ENPP1 | c.578A>T p.E193V | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- EPYC | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERVW-1 | c.1354T>A p.L452I | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ESAM | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EVI5L | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- FAM135B | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM169A | c.1708G>C p.D570H | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM171A1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 70/431 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- FAM83G | c.540G>T p.M180I | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAS | c.506-5T>G | Splice Region (SNP) | VAF 57/249 reads (23%) | called by muse, mutect2, varscan2
- FLRT1 | c.1090del p.R364Gfs*80 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | called by mutect2, pindel, varscan2
- FLT1 | c.2801C>T p.A934V | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- FOXD2 | c.465G>C p.E155D | Missense Mutation (SNP) | VAF 115/457 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- FREM2 | c.2817A>C p.E939D | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FRG2C | c.451A>T p.R151W | Missense Mutation (SNP) | VAF 75/427 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, varscan2
- G6PC2 | c.943C>G p.H315D | Missense Mutation (SNP) | VAF 95/439 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- GBP2 | c.1571A>T p.E524V | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GCK | c.1041G>C p.Q347H | Missense Mutation (SNP) | VAF 49/294 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- GDA | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GFRA2 | c.941C>A p.P314H | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GGNBP2 | c.1614A>T p.K538N | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GLB1L2 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GLDC | c.2454C>G p.I818M | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- GLDC | c.1020G>T p.L340F | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- GLRX3 | c.896G>T p.W299L | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLUD2 | c.1089G>T p.K363N | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GLYAT | c.158T>A p.F53Y | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GMPR | c.220A>C p.T74P | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- GPATCH2 | c.1166A>G p.D389G | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GPR119 | c.182T>G p.L61R | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GPR158 | c.2095A>G p.S699G | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR174 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- GPR32 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GPR63 | c.720G>T p.Q240H | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRM8 | c.1083A>T p.E361D | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- GRXCR1 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 25/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GUCY1A2 | c.149C>A p.P50Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- H2AX | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- HCN2 | c.2492C>A p.A831D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.278); called by muse, varscan2
- HELB | c.1027G>T p.V343L | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- HGSNAT | c.1907G>C p.*636Sext*12 | Nonstop Mutation (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- HOXC9 | c.579G>T p.R193S | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXD9 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HRAS | c.516C>A p.N172K | Missense Mutation (SNP) | VAF 42/363 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGSF8 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 75/409 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL11 | c.504G>T p.W168C | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- IL13RA1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.057); called by muse, varscan2
- IL16 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL31 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2
- INSR | c.3952G>T p.E1318* | Nonsense Mutation (SNP) | VAF 63/297 reads (21%) | called by muse, mutect2, varscan2
- INSRR | c.2942T>A p.I981K | Missense Mutation (SNP) | VAF 42/434 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2
- INTS6 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- IPMK | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- KCNJ3 | c.1327G>C p.V443L | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2
- KCNQ2 | c.1451G>A p.W484* (on ENST00000359125 / NM_172107.4; = p.W456* on NM_004518.6) | Nonsense Mutation (SNP) | VAF 56/360 reads (16%) | called by muse, mutect2, varscan2
- KDR | c.2700_2702delinsAA p.N900Kfs*3 | Frame Shift Del (DEL) | VAF 68/409 reads (17%) | called by pindel, varscan2*
- KEAP1 | c.131_144del p.P44Qfs*30 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | called by mutect2, pindel
- KLHDC10 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.945); called by muse, varscan2
- KLHL32 | c.627+1G>C p.X209_splice | Splice Site (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- KLRB1 | c.371C>A p.T124N | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.917); called by muse, varscan2
- KRTAP10-9 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LAMA3 | c.4047del p.M1350Wfs*81 | Frame Shift Del (DEL) | VAF 58/508 reads (11%) | called by mutect2, pindel, varscan2
- LCAT | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.089); called by muse, mutect2
- LCE2D | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 28/501 reads (6%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.061); called by muse, mutect2
- LETM1 | c.874A>T p.K292* | Nonsense Mutation (SNP) | VAF 17/144 reads (12%) | called by muse, mutect2, varscan2
- LIMCH1 | c.1402A>T p.R468* | Nonsense Mutation (SNP) | VAF 105/354 reads (30%) | called by muse, mutect2, varscan2
- LRP2 | c.1300C>A p.H434N | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- LRPPRC | c.734C>A p.A245D | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- LRRC53 | c.712C>A p.H238N | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MAGI2 | c.1484C>G p.S495C | Missense Mutation (SNP) | VAF 46/397 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MALT1 | c.1622T>C p.L541P | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.37); called by muse, varscan2
- MAPKBP1 | c.4318-2A>T p.X1440_splice (on ENST00000456763 / NM_001128608.2; = p.X1434_splice on NM_014994.3) | Splice Site (SNP) | VAF 10/34 reads (29%) | called by muse, varscan2
- MARCHF4 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MCF2 | c.1565G>A p.R522K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MED12L | c.6349G>T p.A2117S | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, varscan2
- MEIS1 | c.1160G>T p.W387L | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- MFSD2A | c.1504T>G p.F502V (on ENST00000372809 / NM_001136493.3; = p.F489V on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.684); called by muse, mutect2
- MGAM | c.3535G>T p.D1179Y | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MGAM2 | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MICAL2 | c.2513G>T p.G838V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- MMP28 | c.727G>T p.G243C | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MROH6 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 55/377 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MTMR3 | c.2548G>T p.V850L | Missense Mutation (SNP) | VAF 95/386 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.36290G>C p.R12097T | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- MUC16 | c.26799G>T p.Q8933H | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYADML2 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MYOF | c.4915A>T p.I1639F | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- MYPN | c.1430A>G p.D477G | Missense Mutation (SNP) | VAF 73/355 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAV1 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NAV3 | c.5303C>T p.P1768L | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NCAM1 | c.2054T>A p.V685E (on ENST00000316851 / NM_181351.5; = p.V675E on NM_000615.7) | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- NFYC | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NID1 | c.268A>T p.K90* | Nonsense Mutation (SNP) | VAF 62/317 reads (20%) | called by muse, mutect2, varscan2
- NKX2-4 | c.719A>T p.H240L | Missense Mutation (SNP) | VAF 58/494 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NOBOX | c.1503G>T p.E501D | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- NOL11 | c.190A>T p.I64F | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NONO | c.544del p.D182Mfs*34 | Frame Shift Del (DEL) | VAF 34/166 reads (20%) | called by mutect2, pindel, varscan2
- NPAP1 | c.1928C>A p.A643D | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- NRXN1 | c.3816C>A p.Y1272* | Nonsense Mutation (SNP) | VAF 97/424 reads (23%) | called by muse, mutect2, varscan2
- NUP205 | c.1354_1355del p.K452Efs*47 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | called by mutect2, pindel
- NUP210L | c.4969G>C p.E1657Q | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, mutect2
- NUTM2G | c.508G>T p.V170L | Missense Mutation (SNP) | VAF 42/666 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.239); called by muse, mutect2
- OBSCN | c.455A>G p.E152G | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- OR10A2 | c.331G>C p.V111L | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, varscan2
- OR11H12 | c.916A>T p.S306C | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- OR4C16 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR51B4 | c.778A>T p.R260W | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5AC2 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- OR5W2 | c.602C>A p.T201N | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OSER1 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PAK3 | c.1048G>T p.G350C (on ENST00000262836 / NM_001324328.2; = p.G335C on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- PAPPA2 | c.4303C>A p.Q1435K | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARPBP | c.1079T>C p.L360S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAX4 | c.511C>A p.H171N | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PCDH11X | c.874G>T p.V292F | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PCDH15 | c.5206C>A p.P1736T (on ENST00000644397 / NM_001354429.2; = p.P1678T on NM_001142771.2) | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PCLO | c.3307G>T p.E1103* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | called by muse, varscan2
- PCSK5 | c.3074G>C p.G1025A | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- PEAR1 | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 290/627 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- PGK2 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 34/253 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- PKD1 | c.4427C>T p.S1476F | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLCD3 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- POF1B | c.1598C>A p.S533Y | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- PRDM14 | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRDM9 | c.75del p.D26Mfs*29 | Frame Shift Del (DEL) | VAF 203/478 reads (42%) | called by mutect2, pindel, varscan2
- PTPRD | c.64+1G>A p.X22_splice | Splice Site (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- PTPRQ | c.2530G>T p.G844* (on ENST00000616559; = p.G802* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | called by muse, mutect2, varscan2
- PTPRT | c.3309G>T p.M1103I | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PUS7 | c.1262G>T p.C421F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PWP1 | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RABGGTB | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RASGRF2 | c.3303C>A p.N1101K | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- RBMXL3 | c.704C>A p.S235* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- RBPJL | c.1363A>T p.I455F | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RELN | c.9392C>G p.T3131S | Missense Mutation (SNP) | VAF 36/307 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFPL4B | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- ROBO1 | c.3004A>T p.S1002C | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ROBO4 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.40+8G>T | Splice Region (SNP) | VAF 46/295 reads (16%) | called by muse, mutect2, varscan2
- SAAL1 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.34); PolyPhen probably damaging (1); called by muse, varscan2
- SAFB | c.2642G>T p.G881V | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- SCN7A | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- SEC24C | c.2669C>A p.S890Y | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SERPINA9 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SETX | c.2266G>C p.E756Q | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SF3B4 | c.914G>C p.G305A | Missense Mutation (SNP) | VAF 174/342 reads (51%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.794); called by muse, varscan2
- SHOX | c.693C>A p.H231Q | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- SI | c.4877A>T p.K1626M | Missense Mutation (SNP) | VAF 63/282 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SLC17A4 | c.176T>C p.I59T | Missense Mutation (SNP) | VAF 46/458 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, varscan2
- SLC35D2 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- SLC39A12 | c.1626C>G p.I542M (on ENST00000377369 / NM_001145195.2; = p.I505M on NM_152725.3) | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- SLC7A4 | c.291_293delinsCTGC p.R98Cfs*57 | Frame Shift Ins (INS) | VAF 17/80 reads (21%) | called by pindel, varscan2*
- SLC9A3 | c.1548C>A p.S516R | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2
- SMAD5 | c.1305G>T p.W435C | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNED1 | c.2226C>G p.H742Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNRNP200 | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 84/457 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SNRPB | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SON | c.4762G>C p.D1588H | Missense Mutation (SNP) | VAF 58/267 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SP3 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- SPAG17 | c.5017A>T p.T1673S | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.187); called by muse, varscan2
- SPEG | c.6638A>T p.D2213V | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPPL2C | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 58/302 reads (19%) | called by muse, mutect2, varscan2
- SPTA1 | c.5975A>G p.K1992R | Missense Mutation (SNP) | VAF 50/805 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, mutect2
- ST8SIA2 | c.781A>T p.K261* | Nonsense Mutation (SNP) | VAF 60/220 reads (27%) | called by muse, mutect2, varscan2
- SULF1 | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 107/284 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SULF2 | c.1314G>T p.K438N | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- SUN5 | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2
- SUPT20HL1 | c.1634C>A p.A545D | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SUV39H2 | c.31+4A>T | Splice Region (SNP) | VAF 31/123 reads (25%) | called by muse, mutect2, varscan2
- SYT4 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TACC1 | c.62C>A p.A21E | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAS1R2 | c.1567G>T p.G523C | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCF19 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.077); called by muse, mutect2
- TCF4 | c.626G>C p.S209T | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TEX14 | c.2851A>T p.T951S (on ENST00000240361 / NM_001201457.2; = p.T945S on NM_031272.5) | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.02); called by muse, varscan2
- TEX15 | c.2840T>A p.L947Q (on ENST00000256246; = p.L1330Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TG | c.302A>T p.Q101L | Missense Mutation (SNP) | VAF 265/642 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TG | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 51/217 reads (24%) | called by muse, mutect2, varscan2
- TGFB1 | c.457del p.A153Qfs*6 | Frame Shift Del (DEL) | VAF 93/367 reads (25%) | called by mutect2, pindel, varscan2
- TGM7 | c.1740G>T p.K580N | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TMEM241 | c.687C>G p.F229L | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TMEM26 | c.1013C>A p.S338Y | Missense Mutation (SNP) | VAF 109/365 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TNFRSF9 | c.406T>C p.W136R | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- TNN | c.3353G>T p.G1118V | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOP2B | c.4834G>T p.E1612* (on ENST00000264331 / NM_001330700.2; = p.E1607* on NM_001068.3) | Nonsense Mutation (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- TRIM44 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, varscan2
- TRIM6-TRIM34 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TRIT1 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- TRRAP | c.11156G>A p.G3719E (on ENST00000359863 / NM_001244580.1; = p.G3690E on NM_003496.3) | Missense Mutation (SNP) | VAF 24/269 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.596); called by muse, mutect2
- TTBK1 | c.3511C>G p.Q1171E | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBR3 | c.1119G>T p.M373I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, varscan2
- ULK1 | c.2054C>G p.P685R | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- USH2A | c.7809C>A p.C2603* | Nonsense Mutation (SNP) | VAF 88/403 reads (22%) | called by muse, mutect2, varscan2
- VIRMA | c.3317C>G p.P1106R | Missense Mutation (SNP) | VAF 137/388 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- VIT | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- WNK1 | c.5458A>T p.M1820L (on ENST00000315939 / NM_018979.4; = p.M1573L on NM_014823.3) | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK2 | c.829C>A p.L277M | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WNT9A | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZAN | c.1031T>A p.V344E | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZIK1 | c.180T>A p.F60L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- ZNF804A | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF875 | c.1212G>C p.K404N | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1047C>G p.P349= | Silent (SNP) | VAF 32/173 reads (18%) | catalogued as rs771820042; called by muse, mutect2, varscan2
- ADCY8 | c.2727C>T p.L909= | Silent (SNP) | VAF 38/271 reads (14%) | called by muse, mutect2, varscan2
- ANKRD30A | c.2916A>G p.E972= (on ENST00000611781; = p.E916= on NM_052997.2) | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as rs1427873135; called by muse, mutect2, varscan2
- ANKRD31 | c.4890G>T p.G1630= | Silent (SNP) | VAF 49/164 reads (30%) | called by muse, mutect2, varscan2
- ANO4 | c.183C>A p.L61= | Silent (SNP) | VAF 34/410 reads (8%) | called by muse, mutect2
- ANO9 | c.1422C>T p.L474= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- ASTN1 | c.2754A>T p.S918= | Silent (SNP) | VAF 32/311 reads (10%) | called by muse, mutect2, varscan2
- ATP2B3 | c.3081C>A p.P1027= | Silent (SNP) | VAF 27/107 reads (25%) | called by muse, mutect2, varscan2
- AXL | c.2232A>G p.T744= (on ENST00000301178 / NM_021913.5; = p.T735= on NM_001699.6) | Silent (SNP) | VAF 46/211 reads (22%) | called by muse, mutect2, varscan2
- C4orf50 | c.96C>G p.L32= (on ENST00000324058; = p.L1264= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/143 reads (12%) | called by muse, mutect2, varscan2
- CASZ1 | c.2004C>T p.F668= | Silent (SNP) | VAF 40/310 reads (13%) | called by muse, mutect2, varscan2
- CCDC6 | c.195G>C p.S65= | Silent (SNP) | VAF 34/446 reads (8%) | called by muse, mutect2
- CDC14C | c.738C>A p.A246= (on ENST00000428251; = p.A139= on NM_152627.3) | Silent (SNP) | VAF 105/268 reads (39%) | called by muse, mutect2, varscan2
- CETP | c.396C>T p.F132= | Silent (SNP) | VAF 69/592 reads (12%) | catalogued as rs879848326, COSV52362206; called by muse, mutect2, varscan2
- COL22A1 | c.3930C>T p.D1310= | Silent (SNP) | VAF 44/350 reads (13%) | called by muse, mutect2, varscan2
- COMP | c.93C>T p.G31= | Silent (SNP) | VAF 43/305 reads (14%) | called by muse, mutect2, varscan2
- CPED1 | c.1500C>A p.T500= | Silent (SNP) | VAF 31/248 reads (13%) | catalogued as COSV59997289; called by muse, mutect2, varscan2
- CSMD3 | c.7785C>A p.A2595= (on ENST00000297405 / NM_001363185.1; = p.A2491= on NM_052900.3) | Silent (SNP) | VAF 66/362 reads (18%) | catalogued as COSV52243067; called by muse, mutect2, varscan2
- CTNNA2 | c.810C>T p.H270= | Silent (SNP) | VAF 21/234 reads (9%) | catalogued as rs756399817; called by muse, mutect2
- CTNNA2 | c.1332G>C p.G444= | Silent (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- DISC1 | c.534A>T p.P178= | Silent (SNP) | VAF 58/492 reads (12%) | called by muse, varscan2
- DMBX1 | c.609C>A p.P203= | Silent (SNP) | VAF 33/171 reads (19%) | called by muse, mutect2, varscan2
- DNAH10 | c.6861C>A p.A2287= (on ENST00000409039; = p.A2226= on NM_207437.3) | Silent (SNP) | VAF 59/179 reads (33%) | called by muse, mutect2, varscan2
- DNAH6 | c.8832A>G p.V2944= | Silent (SNP) | VAF 36/148 reads (24%) | called by muse, mutect2, varscan2
- ESX1 | c.711G>T p.L237= | Silent (SNP) | VAF 33/133 reads (25%) | called by muse, mutect2, varscan2
- EYS | c.901C>T p.L301= | Silent (SNP) | VAF 27/179 reads (15%) | called by muse, varscan2
- FAM184B | c.2625C>T p.A875= | Silent (SNP) | VAF 78/242 reads (32%) | called by muse, mutect2, varscan2
- FAT3 | c.11253G>A p.Q3751= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as rs1394449491, COSV53174244; called by muse, mutect2, varscan2
- FBN2 | c.3687T>C p.P1229= | Silent (SNP) | VAF 105/403 reads (26%) | called by muse, mutect2, varscan2
- FCRL3 | c.672G>T p.L224= | Silent (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- FRAS1 | c.7947C>T p.L2649= | Silent (SNP) | VAF 78/245 reads (32%) | called by muse, mutect2, varscan2
- FRMPD1 | c.4677G>T p.T1559= | Silent (SNP) | VAF 54/216 reads (25%) | catalogued as COSV66699282, COSV66702444; called by muse, mutect2, varscan2
- GDF3 | c.996C>G p.T332= | Silent (SNP) | VAF 57/263 reads (22%) | called by muse, mutect2, varscan2
- GJB4 | c.537G>T p.R179= | Silent (SNP) | VAF 41/280 reads (15%) | called by muse, mutect2, varscan2
- GREM2 | c.36G>T p.V12= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV58946037; called by muse, varscan2
- GRIN3A | c.672G>A p.V224= | Silent (SNP) | VAF 21/268 reads (8%) | called by muse, mutect2
- H1-5 | c.579C>T p.P193= | Silent (SNP) | VAF 26/408 reads (6%) | catalogued as rs1043555653; called by muse, mutect2
- HAP1 | c.1731G>A p.G577= (on ENST00000310778 / NM_001367460.1; = p.G525= on NM_177977.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/165 reads (16%) | called by muse, mutect2, varscan2
- HGF | c.600C>A p.V200= | Silent (SNP) | VAF 53/243 reads (22%) | catalogued as COSV55957837; called by muse, mutect2, varscan2
- HOXC9 | c.93C>A p.T31= | Silent (SNP) | VAF 135/444 reads (30%) | called by muse, mutect2, varscan2
- IGHG1 | c.9C>A p.T3= | Silent (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- KCNH3 | c.882C>A p.A294= | Silent (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- KLHDC7B | c.1296G>T p.A432= (on ENST00000395676; = p.A1073= on NM_138433.5) | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as COSV67464863; called by muse, mutect2, varscan2
- LCE2D | c.117A>T p.P39= | Silent (SNP) | VAF 28/500 reads (6%) | called by muse, mutect2
- LMOD3 | c.348C>A p.A116= | Silent (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- MAPK10 | c.765A>T p.T255= (on ENST00000359221 / NM_001351625.2; = p.T293= on NM_002753.5) | Silent (SNP) | VAF 43/148 reads (29%) | called by muse, mutect2, varscan2
- MAPKBP1 | c.1851G>T p.T617= (on ENST00000456763 / NM_001128608.2; = p.T611= on NM_014994.3) | Silent (SNP) | VAF 51/231 reads (22%) | called by muse, mutect2, varscan2
- MAST2 | c.2862A>G p.P954= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- MB21D2 | c.969G>T p.R323= | Silent (SNP) | VAF 41/133 reads (31%) | called by muse, mutect2, varscan2
- MELTF | c.651G>T p.L217= | Silent (SNP) | VAF 62/249 reads (25%) | called by muse, mutect2, varscan2
- MUC12 | c.15111C>T p.A5037= (on ENST00000379442; = p.A4894= on NM_001164462.1) | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as rs1320450589; called by muse, mutect2
- MUC16 | c.8706T>A p.T2902= | Silent (SNP) | VAF 33/129 reads (26%) | called by muse, mutect2, varscan2
- MUC17 | c.9996C>A p.T3332= | Silent (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- NOS1 | c.2421C>A p.V807= | Silent (SNP) | VAF 14/177 reads (8%) | called by muse, mutect2
- NRXN1 | c.4014C>A p.P1338= | Silent (SNP) | VAF 44/231 reads (19%) | called by muse, mutect2, varscan2
- NUP153 | c.2004A>T p.L668= | Silent (SNP) | VAF 87/280 reads (31%) | called by muse, mutect2, varscan2
- NYAP2 | c.168C>G p.A56= | Silent (SNP) | VAF 49/207 reads (24%) | called by muse, mutect2, varscan2
- OR10G8 | c.141C>A p.I47= | Silent (SNP) | VAF 72/360 reads (20%) | called by muse, mutect2, varscan2
- OR5A1 | c.351C>T p.L117= | Silent (SNP) | VAF 14/155 reads (9%) | called by muse, mutect2
- OR5AP2 | c.405C>T p.P135= | Silent (SNP) | VAF 51/177 reads (29%) | catalogued as rs374654172, COSV100266444; called by muse, mutect2, varscan2
- OXCT1 | c.45C>T p.A15= | Silent (SNP) | VAF 44/660 reads (7%) | catalogued as rs200780942; called by muse, mutect2
- PABPC5 | c.769C>T p.L257= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs777213774; called by muse, mutect2, varscan2
- PCDH10 | c.1803C>A p.T601= | Silent (SNP) | VAF 60/174 reads (34%) | catalogued as rs1375283661, COSV52091160; called by muse, mutect2, varscan2
- PCDHB13 | c.1320G>C p.L440= | Silent (SNP) | VAF 86/342 reads (25%) | called by muse, mutect2, varscan2
- PCDHB13 | c.1707C>T p.S569= | Silent (SNP) | VAF 108/578 reads (19%) | catalogued as rs781859572; called by muse, mutect2, varscan2
- PCDHB5 | c.361C>T p.L121= | Silent (SNP) | VAF 38/137 reads (28%) | called by muse, mutect2, varscan2
- PCLO | c.6522A>T p.T2174= | Silent (SNP) | VAF 33/229 reads (14%) | called by muse, mutect2, varscan2
- PDE6B | c.24C>A p.A8= | Silent (SNP) | VAF 33/250 reads (13%) | called by muse, mutect2, varscan2
- PLA2R1 | c.2106T>C p.F702= | Silent (SNP) | VAF 24/99 reads (24%) | called by muse, mutect2, varscan2
- PREX1 | c.1614C>A p.T538= | Silent (SNP) | VAF 47/302 reads (16%) | catalogued as COSV64255313; called by muse, mutect2, varscan2
- PTPRN | c.2658C>A p.P886= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV55351539; called by muse, mutect2, varscan2
- RAB11FIP5 | c.558A>C p.P186= | Silent (SNP) | VAF 100/574 reads (17%) | called by muse, mutect2, varscan2
- RABGAP1 | c.1260G>A p.E420= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as rs774136181; called by muse, mutect2, varscan2
- RGS12 | c.3762C>G p.A1254= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- RRAGD | c.1008G>C p.L336= | Silent (SNP) | VAF 15/101 reads (15%) | called by muse, mutect2, varscan2
- RSRC1 | c.561A>G p.L187= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV55836035; called by muse, mutect2, varscan2
- RTN1 | c.1881G>T p.L627= | Silent (SNP) | VAF 96/425 reads (23%) | called by muse, mutect2, varscan2
- RYR2 | c.11070C>A p.A3690= | Silent (SNP) | VAF 31/245 reads (13%) | catalogued as rs1487119561; called by muse, mutect2, varscan2
- RYR3 | c.1758C>A p.S586= | Silent (SNP) | VAF 37/151 reads (25%) | called by muse, mutect2, varscan2
- RYR3 | c.4989C>T p.P1663= | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as rs768997188; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC47A2 | c.1548T>A p.T516= | Silent (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- SLIT2 | c.4482G>T p.P1494= | Silent (SNP) | VAF 21/248 reads (8%) | catalogued as COSV56594672, COSV99886584; called by muse, mutect2
- SOCS4 | c.213T>C p.C71= | Silent (SNP) | VAF 41/233 reads (18%) | called by muse, mutect2, varscan2
- SPTBN2 | c.4050G>C p.L1350= | Silent (SNP) | VAF 71/265 reads (27%) | catalogued as rs760739785; called by muse, mutect2, varscan2
- SRD5A2 | c.477A>T p.I159= | Silent (SNP) | VAF 52/249 reads (21%) | called by muse, mutect2, varscan2
- TAF15 | c.1251C>T p.G417= (on ENST00000605844 / NM_139215.3; = p.G414= on NM_003487.4) | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs765897988; called by muse, mutect2, varscan2
- TAF4 | c.1161C>T p.A387= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs768245528; called by muse, mutect2, varscan2
- TESPA1 | c.895C>A p.R299= (on ENST00000316577 / NM_001098815.3; = p.R161= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 19/190 reads (10%) | catalogued as COSV100344787; called by muse, mutect2, varscan2
- TEX36 | c.297G>A p.K99= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs746076407; called by muse, mutect2, varscan2
- TMEM121 | c.306C>G p.R102= | Silent (SNP) | VAF 56/231 reads (24%) | catalogued as COSV66796151; called by muse, mutect2, varscan2
- TSPOAP1 | c.3747G>T p.V1249= | Silent (SNP) | VAF 42/165 reads (25%) | catalogued as COSV52106280; called by muse, varscan2
- TTC6 | c.216G>T p.T72= | Silent (SNP) | VAF 17/213 reads (8%) | catalogued as COSV101606768; called by muse, mutect2
- USF3 | c.5493G>A p.Q1831= | Silent (SNP) | VAF 27/224 reads (12%) | catalogued as rs746164608; called by muse, mutect2, varscan2
- USH1G | c.1239C>A p.I413= | Silent (SNP) | VAF 88/482 reads (18%) | called by muse, mutect2, varscan2
- VWDE | c.1602T>A p.S534= | Silent (SNP) | VAF 55/145 reads (38%) | called by muse, mutect2, varscan2
- XRN2 | c.2319A>T p.G773= | Silent (SNP) | VAF 31/159 reads (19%) | called by muse, mutect2, varscan2
- ZNF410 | c.459C>G p.L153= | Silent (SNP) | VAF 61/238 reads (26%) | called by muse, mutect2, varscan2
- ZNF521 | c.2604C>A p.S868= | Silent (SNP) | VAF 48/386 reads (12%) | called by muse, mutect2, varscan2
- ZNF536 | c.546G>T p.L182= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as rs574116352, COSV100835819; called by muse, mutect2, varscan2
- ZNF536 | c.1482C>G p.L494= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs1006523266, COSV62817673, COSV62834139; called by muse, mutect2, varscan2
- ZSCAN5A | c.1035G>T p.P345= | Silent (SNP) | VAF 75/254 reads (30%) | called by muse, mutect2, varscan2
- AC006486.1 | c.23-2972C>G | Intron (SNP) | VAF 46/334 reads (14%) | called by muse, mutect2, varscan2
- AC010132.3 | c.-183G>C | 5'UTR (SNP) | VAF 128/306 reads (42%) | called by muse, mutect2, varscan2
- AC139769.1 | n.214-4194A>G | Intron (SNP) | VAF 42/386 reads (11%) | catalogued as rs1409154947; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826634 G>C | 3'Flank (SNP) | VAF 32/124 reads (26%) | called by muse, varscan2
- AL353804.6 | chrX:73826732 A>T | 3'Flank (SNP) | VAF 31/116 reads (27%) | called by muse, varscan2
- AP000769.3 | chr11:65501443 ins A | 5'Flank (INS) | VAF 69/181 reads (38%) | catalogued as rs771258158; called by mutect2, pindel, varscan2
- ATIC | c.-47G>A | 5'UTR (SNP) | VAF 36/102 reads (35%) | catalogued as rs1189377023; called by muse, mutect2
- CHD6 | c.-23-12667C>G | Intron (SNP) | VAF 26/125 reads (21%) | called by muse, mutect2, varscan2
- CLRN1 | c.*1055G>C | 3'UTR (SNP) | VAF 118/587 reads (20%) | called by muse, varscan2
- COLGALT2 | c.833-39T>A | Intron (SNP) | VAF 14/64 reads (22%) | called by muse, varscan2
- DEFA3 | c.*4T>A | 3'UTR (SNP) | VAF 46/214 reads (21%) | called by mutect2, varscan2
- DST | c.2331+38G>C | Intron (SNP) | VAF 28/198 reads (14%) | called by muse, mutect2, varscan2
- EIF4E3 | c.*22T>G | 3'UTR (SNP) | VAF 16/129 reads (12%) | called by muse, mutect2, varscan2
- FAM169B | n.289C>A | RNA (SNP) | VAF 22/99 reads (22%) | catalogued as COSV60571014; called by muse, mutect2, varscan2
- FAM27E5 | n.302C>A | RNA (SNP) | VAF 63/209 reads (30%) | called by muse, mutect2, varscan2
- FASN | c.4288-22G>A | Intron (SNP) | VAF 77/344 reads (22%) | called by muse, mutect2, varscan2
- FOXG1 | chr14:28773426 C>A | 3'Flank (SNP) | VAF 39/191 reads (20%) | called by muse, mutect2, varscan2
- FOXP2 | c.*908C>A | 3'UTR (SNP) | VAF 76/386 reads (20%) | called by muse, mutect2, varscan2
- FYCO1 | c.55+9G>A | Intron (SNP) | VAF 44/484 reads (9%) | called by muse, mutect2
- H2BP2 | n.1061+452C>A | Intron (SNP) | VAF 22/223 reads (10%) | called by muse, mutect2, varscan2
- IGLJ3 | c.-20G>A | 5'UTR (SNP) | VAF 27/207 reads (13%) | catalogued as rs568653495; called by muse, mutect2, varscan2
- IMPA2 | c.490+3478G>A | Intron (SNP) | VAF 4/17 reads (24%) | catalogued as rs571065519; called by mutect2, varscan2
- INPP5B | c.772+108G>T | Intron (SNP) | VAF 50/406 reads (12%) | catalogued as COSV65958068; called by muse, mutect2, varscan2
- KDM5C | c.*191G>T | 3'UTR (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- KRT6B | c.*43C>T | 3'UTR (SNP) | VAF 23/86 reads (27%) | called by muse, varscan2
- LINC02210-CRHR1 | c.-493+11382_-493+11383del | Intron (DEL) | VAF 26/244 reads (11%) | called by mutect2, pindel, varscan2
- LRRC37A17P | n.4058A>G | RNA (SNP) | VAF 22/532 reads (4%) | called by muse, mutect2
- LSM1 | c.115+1006G>C | Intron (SNP) | VAF 11/36 reads (31%) | catalogued as rs562132570; called by muse, mutect2, varscan2
- MBNL1 | c.174+40231G>T | Intron (SNP) | VAF 32/181 reads (18%) | catalogued as COSV56827800; called by muse, mutect2, varscan2
- MIIP | c.1081-32G>T | Intron (SNP) | VAF 40/259 reads (15%) | called by muse, mutect2, varscan2
- MIR515-1 | n.80G>C | RNA (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- MTMR10 | c.-18_-4del | 5'UTR (DEL) | VAF 15/107 reads (14%) | called by mutect2, pindel, varscan2
- Metazoa_SRP | chr17:20342404 C>G | 3'Flank (SNP) | VAF 33/203 reads (16%) | called by muse, mutect2, varscan2
- NFYC-AS1 | n.324G>A | RNA (SNP) | VAF 40/189 reads (21%) | catalogued as COSV65485275; called by muse, mutect2, varscan2
- NMT1 | c.1471-47T>A | Intron (SNP) | VAF 40/198 reads (20%) | called by muse, mutect2, varscan2
- NPHP3 | c.*37G>C | 3'UTR (SNP) | VAF 47/169 reads (28%) | called by muse, mutect2, varscan2
- OBSCN | c.11660-2534G>A | Intron (SNP) | VAF 22/255 reads (9%) | catalogued as rs938557014, COSV52800423; called by muse, mutect2
- PCGF2 | chr17:38749572 G>C | 5'Flank (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- PDE2A | c.703+11G>T | Intron (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- PIGO | c.939+93A>G | Intron (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- PLEC | c.586-168G>T | Intron (SNP) | VAF 57/481 reads (12%) | called by muse, mutect2, varscan2
- PTPRT | c.2176+12087C>A | Intron (SNP) | VAF 57/270 reads (21%) | catalogued as COSV62016054; called by muse, mutect2, varscan2
- RAB40C | chr16:630205 C>G | 3'Flank (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- RBM43 | c.3+248A>G | Intron (SNP) | VAF 18/276 reads (7%) | called by muse, mutect2
- RFK | chr9:76399124 A>T | 5'Flank (SNP) | VAF 67/601 reads (11%) | called by muse, mutect2, varscan2
- RFNG | c.829-131C>T | Intron (SNP) | VAF 14/91 reads (15%) | catalogued as rs561361946; called by muse, mutect2
- RGL3 | c.1329+33G>A | Intron (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792254 T>A | 3'Flank (SNP) | VAF 72/294 reads (24%) | called by muse, mutect2, varscan2
- SLC44A3 | c.278+1244C>T | Intron (SNP) | VAF 44/199 reads (22%) | catalogued as rs1367027362; called by muse, mutect2, varscan2
- SNORD116-9 | n.84G>A | RNA (SNP) | VAF 27/216 reads (13%) | catalogued as rs1307360324; called by muse, mutect2, varscan2
- SNX19 | c.2443+163G>T | Intron (SNP) | VAF 58/314 reads (18%) | catalogued as rs748746372; called by muse, mutect2, varscan2
- SPG7 | c.1304-29C>T | Intron (SNP) | VAF 99/358 reads (28%) | called by muse, mutect2, varscan2
- SSPOP | n.15156G>T | RNA (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- STX18 | chr4:4416115 C>T | 3'Flank (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- SUCO | chr1:172532759 C>G | 5'Flank (SNP) | VAF 18/185 reads (10%) | called by muse, mutect2
- TENM4 | c.*50G>C | 3'UTR (SNP) | VAF 26/279 reads (9%) | catalogued as COSV53657082; called by muse, mutect2, varscan2
- TFCP2 | c.123-6027G>T | Intron (SNP) | VAF 46/502 reads (9%) | called by muse, mutect2
- TPRXL | n.855C>T | RNA (SNP) | VAF 28/284 reads (10%) | called by muse, varscan2
- TRPA1 | c.2295+18C>T | Intron (SNP) | VAF 18/138 reads (13%) | called by muse, varscan2
- TTN | c.34523-114A>G | Intron (SNP) | VAF 47/228 reads (21%) | called by muse, mutect2, varscan2
- TUBB7P | n.1164C>T | RNA (SNP) | VAF 35/287 reads (12%) | called by muse, mutect2, varscan2
- UMPS | c.*1486C>G | 3'UTR (SNP) | VAF 52/294 reads (18%) | called by muse, mutect2, varscan2
- WBP2 | c.-8G>T | 5'UTR (SNP) | VAF 60/229 reads (26%) | catalogued as rs887829011; called by muse, mutect2, varscan2
- ZFP36L1 | chr14:68796046 C>A | 5'Flank (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- ZFP91 | c.*993G>T | 3'UTR (SNP) | VAF 39/196 reads (20%) | called by muse, mutect2, varscan2
